CCDI case PBCBDZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/8c736211-edf8-40cf-aacf-a65dbccc3a96

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 17.0 years (6,225 days).

Biospecimens (3 samples)
- Sample 0DNM9Y: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNMAD: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DNMAX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
